Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5530, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5530-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 9.22 ng/ml and a prostate biopsy in [REDACTED] the biopsy revealed unilateral poorly differentiated prostatic adenocarcinoma: left mid = Gleason grade 3+4=7; left lateral mid = Gleason grade 3+3=6; left lateral apex = Gleason grade 3+4=7; left apex = Gleason grade 3+4=7.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

rh

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPH NODE DISSECTION –
NO EVIDENCE OF NEOPLASIA IN FOUR LYMPH NODES (0/4).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPH NODE DISSECTION –
NO EVIDENCE OF NEOPLASIA IN TWO LYMPH NODES (0/2).

TCGA – EJ – 5530

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3+4=7. GLEASON PATTERN 4 COMPONENT COMPRISES APPROXIMATELY 20% OF THE SAMPLED TUMOR VOLUME.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 2.2 CM.
- C. CARCINOMA INVOLVES 20-25% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. THE CARCINOMA IS CONFINED TO THE PROSTATE GLAND AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. NO PERINEURAL INVASION IS IDENTIFIED.
- F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE BENIGN.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- I. MULTIFOCAL HIGH-GRADE PROSTATE INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. TNM PATHOLOGIC STAGE: pT2c N0 MX.
- K. TNM HISTOLOGIC GRADE = G3-4.
- L. NON-NEOPLASTIC PROSTATE TISSUE WITH NODULAR HYPERPLASIA, FOCAL ACUTE AND CHRONIC INFLAMMATION, AND FOCAL GLANDULAR ATROPHY (SEE SYNOPTIC).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 9.2
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	20%
WEIGHT OF PROSTATE:	57.47gm
TUMOR SIZE:	Maximum dimension: 2.2 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Unknown
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	No
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	6
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 05085ff7-2d4e-4660-bee3-012c016ecae8 (TCGA-EJ-5530.03CB0863-99DB-411A-A347-A8675A65CB5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).